Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24N, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24N-01A (Primary Tumor).

		4/25/11

Final Diagnosis

Breast, left, simple mastectomy: Infiltrating ductal carcinoma, Nottingham grade II (of III), forming a 1.9 x 1.2 x 1.0 cm mass in the superior breast (AJCC pT1c). A minor component of ductal carcinoma in situ, intermediate nuclear grade, is also present. Surgical resection margins are negative for tumor. The nearest (deep) margin is free by 0.2 cm.

Lymph nodes, left axillary sentinel, excision: Multiple (3) left axillary sentinel lymph nodes are negative for tumor. Lymph nodes No.1, and No.2A contain no blue dye, lymph node No.2B contains blue dye. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

Lymph node, left axillary, excision: A single left axillary lymph node is negative for tumor (AJCC pN0).

Her-2/NEU analysis has been ordered on paraffin embedded tissue.

1CD-0-3

carcinoma, infiltrating duct, NOS 8500/3

Site: breast, NOS C50.9 lw
4/25/11

Source: NCI Genomic Data Commons file dc286dcf-24c8-4988-b9ee-63a44386865a (TCGA-AR-A24N.AAF32BB7-716A-4C0E-AE7E-04F6A5BF5628.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).